Surgical pathology report (de-identified scan), TCGA case TCGA-ZG-A9LM, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site University Medical Center Hamburg-Eppendorf, specimen TCGA-ZG-A9LM-01A (Primary Tumor).

[page 1 of 3]
Histopathological Report

Date of cancer sample procurement:

Date of pathology report:

Patient ID:

Gross description:

1. (Prostate gland): Prostate gland: Weight: 45 g, Volume: 40 ml, Size: 4 x 4.5 x 4.9 cm. Adherent seminal vesicles and deferent duct: right side: 3 cm, left side: 1.6 cm. The surface is marked with green ink on the right side, blue ink on the left side. On the right recto-lateral surface a 3.6 x 3.1 cm measuring tissue defect marked with yellow ink. On the left recto-lateral surface a 3.4 x 2.9 cm measuring tissue defect marked with yellow ink. Apical peri-urethral a funnel shaped 0.9 x 0.6 cm tissue defect marked with red ink. Total of the cross sections: 3.1 cm.
2. (Preprostatic fat): 2.4 x 0.7 x 0.7 cm measuring adipose tissue without palpable nodes.
3. (Lymph nodes, right side): 7.5 x 3.5 x 1.6 cm measuring adipose tissue containing 1 nodes measuring up to 1.5 x 1 x 0.6 cm.
4. (Lymph nodes, left side): 5.5 x 5 x 1 cm measuring adipose tissue containing 1 nodes measuring up 3.2 x 0.4 x 0.4 cm.
5. (Neurovascular bundle, right side): Soft tissue measuring 4 x 1 x 0.7 cm.

Microscopy:

1. Apex right and left: Right 3 tissue blocks, left 4 tissue blocks (total 7 tissue blocks). 6 cross sections: Right 12 tissue blocks, left 12 tissue blocks (total 24 tissue blocks). Basis right and left: Right 5 tissue blocks, left 5 tissue blocks (total 10 tissue blocks). Seminal vesicles right and left: Right 4 tissue blocks, left 3 tissue blocks (total 7 tissue blocks). Deferent ducts right and left: Right 1 tissue block, left 1 tissue block (total 2 tissue blocks).
2. Preprostatic fat: 1 tissue block.
3. Frozen lymph nodes right: 4 tissue blocks.
4. Frozen lymph nodes left: 3 tissue blocks.
5. (Neurovascular bundle, right side): 4 tissue blocks.

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Prostate NOS C61.9
9/5/23/14

Diagnosis:

1. (Prostate gland): Poorly differentiated prostatic adenocarcinoma, Gleason 5+3=8, (Gleason 5: 90%, Gleason 3: 10%). Tumor involves the right base. Maximum tumor diameter: 8 mm. Perineural invasion. No tumor infiltration into peri-prostatic adipose tissue. Negative surgical margins peri-urethral and circumferential.

Remaining prostatic tissue with small foci of prostatic intraepithelial neoplasia (high grade PIN) and signs of myoglandular hyperplasia of the prostate. Urothelium of the prostatic urethra without dysplasia. Tumor-free seminal vesicles and deferent ducts.

[page 2 of 3]
2. Preprostatic fat: Tumor-free soft tissue containing nerves and blood vessels.
3. (Lymph nodes, right side): Two lymph node metastases (0.3 and 0.2 mm without extracapsular invasion) in seven lymph nodes (2/7).
4. (Lymph nodes, left side): Four tumor-free lymph nodes (0/4).
5. (Neurovascular bundle, right side): Soft tissue with a minor tumor focus measuring up to 3 mm.

Tumor classification

(in consideration of the intraoperative frozen-section and immunohistochemical analyses):

pT3a, Gleason 4+5=9 (Gleason 4: 55%, Gleason 5: 40%, Gleason 3: 5%), maximum tumor diameter: 25 mm, tumor volume approx. 2.2 ml (Gleason 4: 1.2 ml, Gleason 5: 0.9 ml, Gleason 3: 0.1 ml), pN1 (2/11), L0*, V0, R0

Comments:

The preceding intraoperative frozen section showed more adenocarcinoma areas on the right side with positive surgical margin. The consequently resected right neurovascular bundle showed a minor tumor focus. Assuming, that the resected right neurovascular bundle is adjacent to the intraoperative frozen section marked with yellow ink, the tumor is entirely resected (R0).

Immunohistochemical analyses (AE1/AE3) on eight lymph nodes (tissue blocks 3D-D, 4A) were arranged. Metastases were found in two lymph nodes.

Additionally, immunohistochemical analyses (D2-40, CD 31) on tissue blocks 2F and 2K revealed no lymphatic or venous invasion. Despite the fact no lymphatic or venous invasion was assessed, it has to be assumed that at the point of lymph node metastasis L1 was present.

One macroscopic image for tumor mapping.

*For dx discrepancy form, T6b.1
tumor is Gleason 5+4.*

Criteria:	hw 1/9/14	Yes	No

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

(1 of 1)

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	Gleason 4+5	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	Gleason 5+4	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Frozen sample tissue block submitted to TCGA has a different Gleason score than the frozen tissue block that was used for diagnosis.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file 3dc99c42-6851-4a1b-96c9-590bed1678c4 (TCGA-ZG-A9LM.C66F9B46-7652-4BB9-B554-B9AB372EC7BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).